TARGET case TARGET-30-PAPICY — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c18f2394-5fac-5aef-b36e-6ca61ef1158d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C44.7; Tissue or organ of origin: Skin of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 0.2 years (58 days); Year of diagnosis: 2006; Days to last follow up: 205 days; Cog neuroblastoma risk group: Low Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4S; Mitosis karyorrhexis index: Intermediate.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 205 days; Event-free: no event (relapse, second malignancy or death) recorded through day 205; Year of follow up: 2006.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (3 samples)
- Samples TARGET-30-PAPICY-01A, TARGET-30-PAPICY-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPICY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 205
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.31
- Histology: Favorable
- ICDO Description: Skin of lower limb and hip, Skin of: Ankle, Calf, Foot
